Gene-level copy-number profile of tumor specimen TCGA-55-8097-01A from TCGA case TCGA-55-8097, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.9 years (22,260 days).
Specimen TCGA-55-8097-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e413eb6e-a0f0-4f65-b4bf-68ab47a2b6e7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-8097-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cf1cc9b8-54ce-4509-9d50-b03f0ccce5a7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,161; copy number 2: 49,681; copy number 3: 6,930; copy number 5: 47.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-8097-01A-11D-2237-01): tumor purity 0.64, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 47 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:37,983,007–38,712,103, 33 genes, copy number 5 (within-gene range 3–5): TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP.
- chr20:51,596,514–52,670,578, 14 genes, copy number 5 (within-gene range 3–5): ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4.

Autosomal genes at a single copy (total copy number 1): 3,161. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
